Surgical pathology report (de-identified scan), TCGA case TCGA-23-1117, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Cedars Sinai, specimen TCGA-23-1117-01A (Primary Tumor).

[page 1 of 7]
=====

DIAGNOSIS:

- 3,4: FALLOPIAN TUBES, AND OVARIES, LEFT AND RIGHT, BILATERAL SALPINGO-OOPHORECTOMY:
- Papillary serous neoplasms with focal anaplastic features, grade III, virtually replacing both ovaries, probably representing synchronous primary neoplasms
- Tumor also involves the serosal (capsular) surface of both ovaries and bilateral adnexal soft tissues (ligaments)
- Lymphatic invasion by tumor is present in both adnexa
- Left fallopian tube with papillary serous carcinoma involving mucosa, free-floating in lumen, involving intramural and subserosal lymphatics, and serosal surface
- Right fallopian tube with free-floating fragments of papillary serous carcinoma in lumen and secondary involvement of subserosal and paratubal lymphatics by tumor
- 1,2: SOFT TISSUES, LEFT SIDE WALL AND RIGHT SIDE WALL, EXCISION:
- Metastatic serous carcinoma
- 5-7: SOFT TISSUES, ROUND LIGAMENT, CUL DE SAC "TUMOR" AND PELVIC "TUMOR", EXCISION:
- Metastatic serous carcinoma
- 8: UTERUS, TOTAL ABDOMINAL HYSTERECTOMY:
- Metastatic serous carcinoma involving:
- External surface and outer-most aspect of wall of vagina, virtually to the margin of the vaginal cuff
- External surface and outer muscular wall of posterior cervix
- Serosal surface and external aspect of muscular uterine wall in anterior and posterior lower uterine segments, anterior and posterior uterine corpus and uterine fundus
- Lymphatic invasion by tumor in all involved sites, including lymphatic invasion in outer half of uterine wall
- Right and left parametrial soft tissues
- Small uterine leiomyoma
- Benign inactive/weakly proliferative endometrium with a few cystically dilated glands and foci of ciliated epithelial metaplasia
- Multiple endocervical nabothian cysts
- Chronic cervicitis
- Minimal chronic inflammation of vaginal cuff
- 9: LYMPH NODES, LEFT PELVIC, EXCISION:

[page 2 of 7]
- Three of three lymph nodes positive for metastatic serous carcinoma; one is virtually entirely replaced by tumor (3/3)
- 10: SOFT TISSUE, CUL DE SAC "TUMOR", EXCISION:
- Metastatic serous carcinoma
- 11: LYMPH NODES, LEFT INGUINAL, EXCISION:
- Four of four lymph nodes positive for metastatic serous carcinoma (4/4)
- Tumor is also present in perinodal soft tissue
- 12: SIGMOID COLON, "SIGMOID TUMOR", BIOPSY:
- Metastatic serous carcinoma
- No colonic tissue identified
- 13: SOFT TISSUE AND LYMPH NODES, LEFT PERIAORTIC, EXCISION:
- Agglomerate of at least three lymph nodes, and regional soft tissues showing metastatic carcinoma (3/3)
- Other nodular aggregates of tumor in this specimen may represent additional lymph nodes virtually replaced by carcinoma
- 14: LYMPH NODE, RIGHT PELVIC, EXCISION:
- One lymph node with metastatic serous carcinoma (1/1)
- Tumor also extends into perinodal fat
- 15: LYMPH NODES, RIGHT INGUINAL, EXCISION:
- Seven of eleven lymph nodes positive for metastatic serous carcinoma (7/11)
- Tumor extends into perinodal fat in some areas
- 16: SOFT TISSUE, RIGHT PELVIC SIDE WALL, EXCISION:
- Metastatic serous carcinoma coating peritoneal surface, invading fibroadipose tissue, and invading regional lymphatics
- 17: VERMIFORM APPENDIX, APPENDECTOMY:
- Metastatic serous carcinoma involving mesoappendix, serosal surface of appendix, regional lymphatics, and invading muscular wall, and focally the submucosa of the appendix
- 18-20: OMENTUM, #1, #2, #3, OMENTECTOMY:
- Metastatic papillary serous carcinoma
- Tumor involves regional lymphatics
- Tumor invades omental adipose tissue
- Some small nodular aggregates of tumor may represent omental lymph nodes entirely replaced by metastatic tumor
- Acute and chronic inflammation with reactive follicular lymphoid aggregates
- Exuberant reactive mesothelial proliferation with marked hyperplasia and focal atypia of mesothelial cells
- Numerous psammoma bodies (associated with tumor and reactive mesothelial cells)
- Adhesions
- 21: LYMPH NODE, SMALL BOWEL [MESENTERY], EXCISION:
- One reactive lymph node negative for metastatic carcinoma (0/1)
- 22: SOFT TISSUE, SMALL BOWEL MESENTERY, BIOPSY:
- Metastatic serous carcinoma within regional lymphatic spaces
- Crushed metastatic tumor on serosal surface
- Psammoma body
- Acute and chronic inflammation
- Adhesions
- 23: SOFT TISSUES, RIGHT PERIURETERAL, EXCISION:

[page 3 of 7]
- Metastatic serous carcinoma partially replacing soft tissues
- Lymphovascular invasion by tumor is present

- 24: SOFT TISSUES, LEFT PERIURETERAL, EXCISION:
- Metastatic papillary serous carcinoma involving soft tissues and regional lymphatics
- Adhesions, inflammatory changes, reactive lymphoid aggregates, and fibrosis
- 25: SOFT TISSUE, BLADDER PERITONEUM, EXCISION:
- Metastatic serous carcinoma involving soft tissues and within lymphovascular spaces
- Reactive lymphoid aggregates, inflammatory changes, and adhesions

COMMENT: This appears to represent a high-grade bilateral (synchronous primary) ovarian neoplasm. The tumor exhibits predominantly features of papillary serous carcinoma (though it exhibits glandular, papillary, and solid growth). Some of the neoplastic cells have a hobnail appearance (suggesting the possibility of a minor component of clear cell carcinoma; however, no cytoplasmic clearing is noted). As noted above, some of the tumor cells exhibit anaplastic features. Lymphovascular invasion by tumor is present at virtually all involved sites. Psammoma bodies are seen in association with tumor in most involved sites. The pathologic findings were discussed with [REDACTED]

=====

HISTORY: Ovarian carcinoma

MICROSCOPIC:
See Diagnosis.

GROSS:

1: LEFT SIDE WALL TUMOR

Labeled "left side wall tumor" and received in formalin is a 2.5 x 2.5 x 1.3 cm aggregate of irregular fragments of firm, tan-red tumor. Representative sections are submitted.

A. 4

2: RIGHT SIDE WALL TUMOR

Labeled "right side wall tumor" and received in formalin is a 3.5 x 1.5 x 0.5 cm fragment of firm, tan-red tumor. Representative sections are submitted.

B. 3

3: LEFT TUBE AND OVARY

Labeled "left tube and ovary", received fresh in the Operating Room, used for intraoperative diagnosis and subsequently fixed in formalin, is a 130 gram ovary with attached fallopian tube. The ovary measures 9.5 x 4.5 x 3.4 cm. The capsule of the ovary is tan and smooth and covered by scattered implants of tan tumor. Sectioning demonstrates the ovary to be entirely replaced by tumor. The tumor is generally solid and has a semisoft tan cut surface separated by intervening fibrous tissue. In some areas the tumor has a papillary appearance. The attached fallopian tube measures 6.2 cm in length x 1.0 cm in diameter. The serosal surface of the fallopian tube and mesosalpinx are covered by scattered implants of tumor. Sectioning of the fallopian tube reveals a dilated lumen measuring 0.5 cm in diameter. The tumor appears to focally invade the wall of the fallopian tube tube approximately 1.5 cm from the fimbriated end. Representative sections are submitted.

[page 4 of 7]
C-F. Tumor - 2 each
G,H. Tumor with fallopian tube - 1 each
YY. Remnant of frozen section - 1

4: RIGHT TUBE AND OVARY

Labeled "right tube and ovary" and received in formalin is a 230 gram ovary with attached fallopian tube. The ovary measures 11.2 x 5.5 x 5.5 cm. The external surface of the ovary is tan and smooth and covered by scattered tumor implants which range in size from 0.3 x 0.2 x 0.1 cm to 1.0 x 0.7 x 0.2 cm. The entire ovary is replaced by a soft, tan-yellow, generally solid tumor. There is some intervening white fibrous tissue. Foci of necrosis and fibrosis are noted within the neoplasm. Some areas of tumor have a papillary appearance. The attached fallopian tube measures 5.5 cm in length x 1.2 cm in diameter. The serosal surface of the fallopian tube is tan and smooth. Sectioning of the fallopian tube reveals a patent lumen measuring 0.1 cm. There is no gross involvement of the fallopian tube by tumor. Representative sections are submitted.

I-N. Tumor - 2 each
O,P. Fallopian tube - 2 each

5: ROUND LIGAMENT

Labeled "round ligament" and received in formalin is a 12.5 x 5.0 x 0.5 cm fragment of firm, tan, ligamentous tissue diffusely coated by nodular aggregates of tan tumor. Representative sections are submitted.

Q. 3

6: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin is a 3.5 x 3.5 x 0.7 cm aggregate of irregular, firm, tan tumor fragments. Representative sections are submitted.

R. 3

7: PELVIC TUMOR

Labeled "pelvic tumor" and received in formalin are multiple fragments of firm, tan tumor with attached blood clot amounting in aggregate to about 5.5 x 4.6 x 0.9 cm. Representative sections are submitted.

S. 3

8: UTERUS

Labeled "uterus", received fresh in the Operating Room and subsequently fixed in formalin, is a 100 gram uterus with attached cervix. The uterus measures 6.0 cm from cornu to cornu, 2.5 cm from anterior to posterior and 9.0 cm from the fundus to ectocervix. The serosal surface of the uterus is coated by scattered implants of firm, tan tumor which range in size from 0.3 x 0.3 x 0.3 cm to 3.0 x 2.2 x 0.3 cm. The right and left parametrial tissue is also grossly involved by tumor. The attached cervix measures 3.3 cm in length x 3.5 cm in diameter. The ectocervix has a surface area of 3.5 x 3.0 cm and has a central patent os measuring 0.6 cm in diameter. The squamous mucosa is tan-white and generally smooth. The paracervical tissue also appears to be grossly involved by tumor. The endocervical canal measures 2.5 cm in length with a maximal width of 1.0 cm. The endocervical canal has a tan, rugose mucosa and several mucus filled nabothian cysts. The uterine cavity measures 4.5 cm in length with a maximal width of 2.5 cm. The endometrium is pale tan and has a thickness of 0.1 cm. The myometrium has a firm, tan, somewhat trabeculated cut surface with a maximum thickness of 2.8 cm. Sectioning the myometrium reveals no primary intramural uterine lesions. Representative sections are submitted.

[page 5 of 7]
- T. Anterior cervix - 1
- U. Posterior cervix and vaginal cuff - 1
- V. Anterior lower uterine segment - 1
- W. Posterior lower uterine segment - 1
- X. Anterior uterine corpus - 1
- Y. Posterior uterine corpus - 1
- Z. Anterior fundus - 1
- AA. Posterior fundus - 1
- BB. Left parametrial tissue - 1
- CC. Right parametrial tissue - 1

9: LEFT PELVIC NODE

Labeled "left pelvic node" and received in formalin is a 2.5 x 1 x 0.7 cm agglomerate of several firm tan lymph nodes that are partially replaced by yellow-tan metastatic tumor. The entire specimen is embedded.

- DD. Three lymph nodes - 2

10: CUL DE SAC TUMOR

Labeled "cul de sac tumor" and received in formalin is a 4.5 x 4.5 x 1.0 cm aggregate of irregular fragments of firm, tan tumor. Representative sections are submitted.

- EE. 3

11: LEFT INGUINAL NODE

Labeled "left inguinal node" and received in formalin are four firm, tan lymph nodes which grossly appear to be partially replaced by tan-yellow tumor. The lymph nodes range in size from 1.5 to 4.5 cm in greatest dimension. The lymph nodes are all embedded.

- FF. One lymph node - 2
- GG. One lymph node - 2
- HH. One lymph node - 2
- II. One lymph node - 2

12: SIGMOID TUMOR

Labeled "sigmoid tumor" and received in formalin is a 2.5 x 1.5 x 0.6 cm aggregate of irregular, firm, tan fragments of tumor. Representative sections are submitted.

- JJ. 3

13: LEFT PERIAORTIC LYMPH NODE

Labeled "left periaortic lymph node" and received in formalin is a 3.5 x 2.7 x 0.9 cm agglomerate of several firm lymph nodes, which appear to be replaced by metastatic tumor, several firm tan tumor nodules, possibly also representing lymph nodes replaced by metastatic tumor, and some adjacent fibroadipose tissue. The entire specimen is embedded.

- KK. Agglomerate of multiple lymph nodes and soft tissues - Multiple

14: RIGHT PELVIC NODE

Labeled "right pelvic node" and received in formalin is a 3.5 x 1 x 1 cm firm tan lymph node which is partially replaced by metastatic firm tan-white tumor. Also received in the same specimen container is a 1.5 x 0.7 x 0.5 cm fragment of soft tissue that is also replaced by firm, tan-white tumor. The entire specimen is embedded.

- LL. One lymph node and soft tissue with metastatic tumor - 2

15: RIGHT INGUINAL NODE

Labeled "right inguinal node" and received in formalin are two agglomerates of soft tissues and lymph nodes measuring about 1.5 x 1.2 x 0.6 cm and 3 x 2 x 1 cm. Some of the lymph nodes are matted

[page 6 of 7]
together rendering assessment of the total number of lymph nodes virtually impossible on gross inspection. The obvious nodal tissue ranges from about 0.3 to 2.5 cm in greatest dimension. Some of the nodal tissue appears to be replaced by firm, tan-white metastatic tumor. The lymph nodes are entirely embedded along with some of the adjacent adipose tissue.

MM. Several lymph nodes and adipose tissue - 2

NN. Agglomerate of several lymph nodes - 2

16: RIGHT PELVIC SIDE WALL

Labeled "right pelvic side wall" and received in formalin is a 5.5 x 3.2 x 0.5 cm fragment of yellow-tan fibrous tissue and adipose tissue which is partially coated by firm, tan-white tumor nodules. The tumor nodules range from 0.3 to 2 cm in greatest dimension. Representative sections are submitted.

OO. 2

17: APPENDIX

Labeled "appendix" and received in formalin is an appendix measuring 5.4 cm in length x 0.7 cm in diameter. The attached periappendiceal fat measures 4.2 x 0.7 x 0.4 cm. The appendix has a wall thickness of 0.2 cm and a patent lumen which measures 0.2 cm in diameter. Nodular aggregates of firm, tan-white tumor are present in the mesentery and involve the serosal surface of the appendix. No infiltrative tumor is grossly evident. Representative sections are submitted.

PP. Proximal, mid portion, and distal appendix and adjacent mesoappendix - 3

18: OMENTUM NO.1

Labeled "omentum #1" and received in formalin is a 15.0 x 4.0 x 0.5 cm fragment of lobulated yellow omental fat, showing adhesions, but no gross evidence of tumor. Representative sections are submitted.

QQ. 2

19: OMENTUM NO.2

Labeled "omentum #2" and received in formalin is a 10.5 x 9.0 x 0.4 cm fragment of lobulated omental fat. No gross tumor is seen. Representative sections are submitted.

RR. 2

20: OMENTUM NO.3

Labeled "omentum #3" and received in formalin is a 13.5 x 2.2 x 0.5 cm fragment of lobulated omental fat, within which there are a few small nodular aggregates of firm tan-white tumor, the largest of which measures about 0.5 cm in diameter. Representative sections are submitted.

SS. 2

21: SMALL BOWEL LYMPH NODE

Labeled "small bowel lymph node" and received in formalin is a single soft tan lymph node measuring 0.6 x 0.5 x 0.3 cm. There is no gross evidence of tumor. The entire specimen is embedded.

TT. 1

22: SMALL BOWEL MESENTERY

Labeled "small bowel mesentery" and received in formalin is a 1.1 x 0.6 x 0.2 cm fragment of mesenteric fat with a 0.6 x 0.5 x 0.2 cm adherent plaque of firm, white tumor. The entire specimen is embedded.

[page 7 of 7]
UU. 1

23: RIGHT PERIURETERAL TUMOR

Labeled "right periureteral tumor" and received formalin is a 4.5 x 2.2 x 0.5 cm fragment of firm, white tumor. Representative sections are submitted.

VV. 2

24: LEFT PERIURETERAL TUMOR

Labeled "left periureteral tumor" and received in formalin is a 3.5 x 1.2 x 0.3 cm fragment of tan-red, fibrous tissue with adherent implants of firm, white tumor ranging in size from 0.1 x 0.1 x 0.1 cm to 1.5 x 0.9 x 0.2 cm. Representative sections are submitted.

WW. 2

25: BLADDER PERITONEUM

Labeled "bladder peritoneum" and received in formalin is a 1.5 x 1 x 0.3 cm fragment of red-tan fibrous tissue with adhesions and several nodular aggregates of firm, tan-white tumor, the largest of which measures about 0.3 cm in diameter. The entire specimen is embedded.

XX. 1

OPERATIVE CONSULT (GROSS)

#8. Endometrium unremarkable

OPERATIVE CONSULT (FROZEN):

#3 FS. Undifferentiated malignant tumor

- ?Carcinoma

- ?Granulosa cell

Wait for paraffin section

gonogenic

Special Studies: Frozen Section

Source: NCI Genomic Data Commons file 8595a0b9-d4d7-470d-8e89-42c4277faeb7 (TCGA-23-1117.ABC636A1-677D-49E5-9259-5B5B828A575E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).